Somatic mutation profile of tumor specimen C3L-02649-04 (aliquot CPT0204800006) from CPTAC case C3L-02649, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 62.3 years (22,773 days).
Specimen C3L-02649-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7073d6ba-82b4-4ec5-a05d-410e8d5be7fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02649-31 (Blood Derived Normal), aliquot CPT0204930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/752e968f-fede-424b-a3f5-95936c033271

The open-access MAF lists 422 somatic variants for this specimen: 262 protein-altering or splice-affecting, 97 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 97, Intron 27, Nonsense Mutation 19, 3'UTR 13, 5'UTR 9, RNA 7, Frame Shift Del 7, Splice Site 6, 5'Flank 4, Splice Region 4, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.12544G>C p.E4182Q | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs397516508, COSV100773463; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 152/286 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTBL2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs751919928; called by muse, mutect2, varscan2
- ADCY7 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200651932, COSV54272373; called by muse, mutect2, varscan2
- ADIPOQ | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.034); catalogued as COSV57859979; called by muse, mutect2, varscan2
- AMZ1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 193/536 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs748259042; called by muse, mutect2, varscan2
- ANKRD30B | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100746498; called by muse, mutect2, varscan2
- AP1B1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 144/415 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs998775154; called by muse, mutect2, varscan2
- ATM | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as COSV53735669; called by muse, mutect2, varscan2
- ATM | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs765847854, COSV99591671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP3 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66511768; called by muse, mutect2, varscan2
- CACNA1I | c.5321G>A p.R1774Q | Missense Mutation (SNP) | VAF 167/436 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs925854645; called by muse, mutect2, varscan2
- CAMKK1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1446600000; called by muse, mutect2, varscan2
- CAMTA2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.955); catalogued as rs758029821; called by muse, mutect2
- CAP2 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285369064; called by muse, mutect2, varscan2
- CCR9 | c.556T>C p.Y186H (on ENST00000357632 / NM_031200.3; = p.Y174H on NM_006641.4) | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374047706; called by muse, mutect2, varscan2
- CD1E | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV63770787, COSV63773186; called by muse, mutect2, varscan2
- CDH10 | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 596/954 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV52581808; called by muse, mutect2, varscan2
- CFAP54 | c.7888C>T p.Q2630* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV61573061; called by muse, mutect2, varscan2
- CHSY3 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as rs1383185867, COSV100518716, COSV59288152; called by muse, mutect2, varscan2
- CLDN5 | c.226G>C p.E76Q (on ENST00000618236 / NM_001363066.2; = p.E161Q on NM_003277.4) | Missense Mutation (SNP) | VAF 144/574 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV54243409; called by muse, mutect2, varscan2
- COBL | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs749249733, COSV54344223; called by muse, mutect2, varscan2
- CRTC2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 163/778 reads (21%) | catalogued as COSV57841169, COSV57843903; called by muse, mutect2, varscan2
- CST7 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs770020061, COSV54176280; called by muse, mutect2, varscan2
- CTNNA3 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs780346090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR4 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 131/420 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54013014; called by muse, mutect2, varscan2
- CYP2C9 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as CM1412028; called by muse, mutect2, varscan2
- DKK2 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV99569665; called by muse, mutect2, varscan2
- DNAH14 | c.1869C>A p.F623L (on ENST00000445597; = p.F652L on NM_001367479.1) | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV101464382; called by muse, mutect2, varscan2
- DNAH3 | c.6941G>A p.R2314H | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771648891, COSV54556823; called by muse, mutect2, varscan2
- DOCK8 | c.4003G>T p.V1335L | Missense Mutation (SNP) | VAF 319/520 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs141863163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF4A2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 174/277 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs1560083657; called by muse, mutect2, varscan2
- EME2 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV51599133; called by muse, mutect2, varscan2
- EOMES | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 88/500 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55411225; called by muse, mutect2, varscan2
- EP300 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 222/656 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV54335371, COSV54346086; called by muse, mutect2, varscan2
- EPHA6 | c.2284G>T p.G762C (on ENST00000389672 / NM_001080448.3; = p.G154C on NM_173655.4) | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101065698; called by muse, mutect2, varscan2
- FAAP20 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1354466402; called by muse, mutect2, varscan2
- FAM111A | c.1485G>C p.K495N | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100659348; called by muse, mutect2, varscan2
- GGT7 | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as rs1205719209; called by muse, mutect2, varscan2
- GLCCI1 | c.*4dup | Frame Shift Ins (INS) | VAF 28/100 reads (28%) | catalogued as rs751454391; called by mutect2, pindel
- GTF3C1 | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs746001492; called by muse, mutect2, varscan2
- H1-2 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 106/784 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59190705, COSV59193232; called by mutect2, varscan2
- H2AC16 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 132/444 reads (30%) | catalogued as rs1412896073; called by muse, mutect2, varscan2
- H2BC4 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 211/846 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV58415578, COSV58417740; called by muse, mutect2, varscan2
- HERC1 | c.4529C>G p.S1510W | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs757745102, COSV71247205; called by muse, mutect2, varscan2
- IGHMBP2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 242/640 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs374952782; called by muse, mutect2, varscan2
- IGKV1-27 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs767124175; called by muse, mutect2, varscan2
- IGSF10 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs746257775, COSV56792481; called by muse, mutect2
- KEAP1 | c.712A>C p.N238H | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV50279719; called by muse, mutect2, varscan2
- KLHL40 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55132599; called by muse, mutect2, varscan2
- LRIG3 | c.2728G>C p.D910H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs764211830; called by muse, mutect2, varscan2
- MAGEB5 | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1490515623; called by muse, mutect2, varscan2
- MAN2B2 | c.491C>A p.A164E | Missense Mutation (SNP) | VAF 124/258 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753497334; called by muse, mutect2, varscan2
- MED12 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV61334635; called by muse, mutect2, varscan2
- MFSD6 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV55623328; called by muse, mutect2, varscan2
- MTCH1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 76/348 reads (22%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.891); catalogued as COSV65319526; called by muse, mutect2, varscan2
- MUC4 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 60/676 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV62125595, COSV62190452; called by muse, mutect2
- MUC5B | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs758916290; called by muse, mutect2, varscan2
- MYO15B | c.7774-5C>T | Splice Region (SNP) | VAF 84/376 reads (22%) | catalogued as rs1460184664; called by muse, mutect2
- NECTIN3 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1370012514; called by muse, mutect2, varscan2
- NEU4 | c.550C>T p.R184* (on ENST00000391969 / NM_001167602.3; = p.R196* on NM_080741.4) | Nonsense Mutation (SNP) | VAF 17/462 reads (4%) | catalogued as rs767645970; called by muse, mutect2
- NIPA1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV61679341, COSV61680467; called by muse, mutect2, varscan2
- NLGN2 | c.1964C>G p.P655R | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1395904083; called by muse, mutect2, varscan2
- NONO | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV52139237; called by muse, mutect2
- NXPE2 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64941260; called by muse, mutect2
- OR14C36 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs917019668; called by muse, mutect2, varscan2
- OTUD4 | c.2822C>T p.S941F (on ENST00000447906 / NM_001366057.1; = p.S876F on NM_001102653.1) | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV71381610; called by muse, mutect2, varscan2
- P4HA1 | c.1106T>C p.I369T | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs774888932; called by muse, mutect2, varscan2
- PCDHB5 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV99168713; called by muse, mutect2, varscan2
- PCLO | c.9298A>G p.T3100A | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs775181689; called by muse, mutect2, varscan2
- PCLO | c.6988C>T p.R2330* | Nonsense Mutation (SNP) | VAF 45/280 reads (16%) | catalogued as COSV61671534; called by muse, mutect2, varscan2
- PCLO | c.3253C>T p.Q1085* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV61674478; called by muse, mutect2
- PIK3C2G | c.3254C>A p.S1085* (on ENST00000676171; = p.S1044* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as COSV56797178; called by muse, mutect2, varscan2
- PIK3CA | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.076); catalogued as COSV55891134, COSV55893970; called by muse, mutect2, varscan2
- PTPRT | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630873; called by muse, mutect2, varscan2
- RASGRF2 | c.1642G>T p.G548W | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1385468033; called by muse, mutect2, varscan2
- RASSF9 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV63435801; called by muse, mutect2, varscan2
- RB1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 95/133 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs763377384; called by muse, mutect2, varscan2
- RC3H2 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV61799977; called by muse, mutect2, varscan2
- RCOR1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs886637077; called by muse, mutect2, varscan2
- RGS9 | c.687C>T p.I229= | Splice Region (SNP) | VAF 64/398 reads (16%) | catalogued as rs371275167; called by muse, mutect2, varscan2
- RIMS3 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 243/490 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as rs1211309483; called by muse, mutect2, varscan2
- ROM1 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 144/687 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371141320; called by muse, mutect2, varscan2
- ROS1 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63857484; called by muse, mutect2, varscan2
- RTN2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 273/531 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as rs1301285695; called by muse, mutect2, varscan2
- SIPA1L3 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs756546599, COSV55918999; called by muse, mutect2, varscan2
- SOAT2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV56860938; called by muse, mutect2, varscan2
- SPAST | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 100/582 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs1553394603, CM030280, CM051993, COSV100188301; called by muse, mutect2, varscan2
- SPTA1 | c.6093G>T p.L2031F | Missense Mutation (SNP) | VAF 95/468 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777450022, COSV100934964, COSV63758830, COSV63760737; called by muse, mutect2, varscan2
- SSH3 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV57385857; called by muse, mutect2, varscan2
- SUCLG2 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV72330731; called by muse, mutect2, varscan2
- SV2C | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs369286225; called by muse, mutect2, varscan2
- SYNJ2 | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV100839974; called by muse, mutect2, varscan2
- TAF5L | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 107/502 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV99273624; called by muse, mutect2, varscan2
- TBX21 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99456407; called by muse, mutect2, varscan2
- TMEM132D | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV67160439; called by muse, mutect2, varscan2
- TTC28 | c.5188G>C p.E1730Q | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1336312569; called by muse, mutect2, varscan2
- VCAN | c.891del p.W298Gfs*11 | Frame Shift Del (DEL) | VAF 31/236 reads (13%) | catalogued as COSV99425009; called by mutect2, pindel, varscan2
- ZNF202 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV100278959; called by muse, mutect2, varscan2
- ZNF521 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs149969134; called by muse, mutect2, varscan2
- A2ML1 | c.1828C>A p.R610S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AARS2 | c.1150-1G>A p.X384_splice | Splice Site (SNP) | VAF 235/868 reads (27%) | called by muse, mutect2, varscan2
- ABCA10 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCA12 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ACACB | c.3797T>C p.L1266S | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP2 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 70/891 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ADAMTS1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- AGRN | c.1092C>G p.Y364* | Nonsense Mutation (SNP) | VAF 75/331 reads (23%) | called by muse, mutect2, varscan2
- AKAP9 | c.10958G>C p.G3653A (on ENST00000359028; = p.G3629A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ANK2 | c.1132T>A p.Y378N | Missense Mutation (SNP) | VAF 143/275 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ANO1 | c.2469G>C p.K823N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ARFGAP3 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 63/416 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARHGAP5 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 192/469 reads (41%) | called by muse, mutect2, varscan2
- ARRB1 | c.1023-2A>G p.X341_splice | Splice Site (SNP) | VAF 85/170 reads (50%) | called by muse, mutect2, varscan2
- ASPM | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 33/445 reads (7%) | called by muse, mutect2
- ATF7IP | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- ATP11C | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATPAF1 | c.689G>T p.R230L (on ENST00000574428; = p.R253L on NM_022745.4) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BDKRB2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C20orf194 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C5orf49 | c.404G>T p.S135I | Missense Mutation (SNP) | VAF 189/291 reads (65%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- C8orf48 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASP1 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 65/603 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- CCDC170 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CCDC172 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- CDC42BPG | c.3809del p.P1270Hfs*60 | Frame Shift Del (DEL) | VAF 287/835 reads (34%) | called by mutect2, pindel, varscan2
- CEP295 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNTN2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 58/628 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CRAT | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CUBN | c.10501G>A p.E3501K | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CXXC1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CYBC1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- DAB2IP | c.1975_1978dup p.Q660Rfs*8 (on ENST00000408936; = p.Q632Rfs*8 on NM_032552.3) | Frame Shift Ins (INS) | VAF 83/223 reads (37%) | called by mutect2, pindel, varscan2
- DACT1 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 148/318 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DCTN3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- DEPDC5 | c.3023C>G p.P1008R (on ENST00000400246; = p.P1077R on NM_014662.5) | Missense Mutation (SNP) | VAF 162/401 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHFR2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL2 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- DSCAML1 | c.3554G>T p.G1185V (on ENST00000321322; = p.G1125V on NM_020693.4) | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELF4 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ERMP1 | c.2602T>C p.Y868H | Missense Mutation (SNP) | VAF 122/195 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- F9 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 76/128 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM171B | c.2053G>T p.V685L | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- FAM234B | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- FBXO47 | c.762T>G p.Y254* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- FHL1 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FKBP8 | c.1033G>A p.E345K (on ENST00000222308 / NM_001308373.2; = p.E346K on NM_012181.5) | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- FRAS1 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GEN1 | c.1203-1G>A p.X401_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- GLI2 | c.2897G>A p.R966Q (on ENST00000361492 / NM_001374353.1; = p.R983Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/752 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GPR155 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/359 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- GPR158 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 116/443 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- H6PD | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 88/542 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- HECA | c.683del p.P228Qfs*71 | Frame Shift Del (DEL) | VAF 63/220 reads (29%) | called by mutect2, pindel, varscan2
- HMX2 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HOXB6 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 242/623 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- IFNL1 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IL22 | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPP5B | c.1066G>A p.G356R (on ENST00000373023; = p.G276R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRIPL1 | c.1412C>T p.S471F (on ENST00000439118 / NM_001008949.3; = p.S479F on NM_178495.6) | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LARP1B | c.154T>A p.L52I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LINGO1 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LONP2 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 174/520 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LOXHD1 | c.5800A>G p.N1934D (on ENST00000642948; = p.N1872D on NM_144612.7) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- LPA | c.4943A>C p.H1648P | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPIN3 | c.1888A>T p.T630S | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LPL | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 124/244 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRTM4 | c.186del p.S63Hfs*6 | Frame Shift Del (DEL) | VAF 195/463 reads (42%) | called by mutect2, pindel, varscan2
- MAGI3 | c.1077-2A>G p.X359_splice | Splice Site (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- MAN2B1 | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 139/286 reads (49%) | called by muse, mutect2, varscan2
- MAP4K1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MARCHF7 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- MAST3 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MDN1 | c.5331C>G p.I1777M | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MID1 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MROH9 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC4 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 46/658 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); called by muse, mutect2
- NID2 | c.2395T>C p.C799R | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by mutect2, varscan2
- NMT1 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- NRK | c.2281C>T p.H761Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- NSRP1 | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OBSCN | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 90/866 reads (10%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.926); called by muse, varscan2
- OR52A5 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OTX1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 196/571 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PCDHB5 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 128/321 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PGM2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIK3R4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PIP5K1A | c.931G>A p.D311N (on ENST00000368888 / NM_001135638.2; = p.D298N on NM_003557.3) | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKD2L1 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PPFIA3 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.045); called by muse, mutect2
- PPL | c.3680A>T p.E1227V | Missense Mutation (SNP) | VAF 202/518 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PREX2 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 115/511 reads (23%) | called by muse, mutect2, varscan2
- PREX2 | c.2438del p.D813Afs*27 | Frame Shift Del (DEL) | VAF 22/192 reads (11%) | called by mutect2, pindel, varscan2
- PRR30 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRRC2C | c.5276C>G p.S1759* (on ENST00000367742; = p.S1757* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 133/601 reads (22%) | called by muse, mutect2, varscan2
- PRUNE1 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 142/593 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RANBP17 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- RANBP2 | c.2194del p.V732Sfs*11 | Frame Shift Del (DEL) | VAF 79/386 reads (20%) | called by mutect2, pindel, varscan2
- RAP2C | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RBM34 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | called by muse, mutect2, varscan2
- REX1BD | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.069); called by muse, mutect2
- RLF | c.4237C>T p.Q1413* | Nonsense Mutation (SNP) | VAF 50/192 reads (26%) | called by muse, mutect2, varscan2
- RNF103 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ROPN1L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 232/328 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPL8 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RPTN | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 94/1140 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2
- RTEL1 | c.3010C>G p.P1004A | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- RUSC1 | c.2423C>G p.S808C (on ENST00000368352 / NM_001105203.2; = p.S339C on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SART1 | c.1262A>G p.D421G | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SERPINB2 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SERPINE1 | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 120/275 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SHCBP1L | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 110/502 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC15A5 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC22A1 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SLC27A5 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC35C1 | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 249/522 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC5A8 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SOAT2 | c.461A>C p.D154A | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- SPRYD3 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2
- SPTA1 | c.5144T>C p.L1715S | Missense Mutation (SNP) | VAF 309/665 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STKLD1 | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SULF2 | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNGR3 | c.483G>A p.V161= | Splice Region (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- TAF12 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBL1XR1 | c.766+1G>C p.X256_splice | Splice Site (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- TBX5 | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 68/351 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TCEA2 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TCHH | c.52T>C p.Y18H | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- TCHHL1 | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TDRD9 | c.3067C>T p.L1023F | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TENM4 | c.7284G>C p.W2428C | Missense Mutation (SNP) | VAF 305/673 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD1 | c.1619T>C p.M540T | Missense Mutation (SNP) | VAF 235/369 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TM9SF4 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TMEM121B | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 221/905 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMEM135 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TOP2A | c.2170C>G p.P724A | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPTE | c.940C>A p.Q314K (on ENST00000618007 / NM_199261.4; = p.Q296K on NM_199259.4) | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2
- TRAPPC1 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTF2 | c.1392_1397del p.T465_N466del | In Frame Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- TUBB2B | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 101/603 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UNC13D | c.859-8C>T | Splice Region (SNP) | VAF 139/686 reads (20%) | called by muse, mutect2, varscan2
- USH2A | c.9931G>A p.E3311K | Missense Mutation (SNP) | VAF 157/751 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VAX1 | c.169G>C p.A57P | Missense Mutation (SNP) | VAF 202/388 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- VWA5B1 | c.2042C>A p.A681D | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- WDR13 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- WDR54 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- XYLB | c.1526C>G p.A509G | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- YWHAH | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 275/818 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H10 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZDHHC13 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYND15 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF180 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF384 | c.1532A>T p.Q511L (on ENST00000361959; = p.Q450L on NM_133476.5) | Missense Mutation (SNP) | VAF 60/571 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.641); called by muse, mutect2
- ZNF414 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF507 | c.766A>C p.T256P | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF71 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF804A | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF804B | c.3409A>T p.K1137* | Nonsense Mutation (SNP) | VAF 69/193 reads (36%) | called by muse, mutect2, varscan2
- ZNF98 | c.648del p.A218Pfs*41 | Frame Shift Del (DEL) | VAF 52/146 reads (36%) | called by mutect2, pindel, varscan2
- ZNF99 | c.1571T>A p.L524H | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC131160.1 | c.762T>A p.V254= | Silent (SNP) | VAF 33/257 reads (13%) | catalogued as COSV57702556; called by muse, mutect2, varscan2
- ACTN2 | c.2241G>T p.A747= | Silent (SNP) | VAF 74/724 reads (10%) | catalogued as COSV63975321; called by muse, mutect2, varscan2
- ADH1C | c.402C>T p.S134= | Silent (SNP) | VAF 91/330 reads (28%) | catalogued as rs532369179; called by muse, mutect2, varscan2
- APP | c.2127T>C p.G709= | Silent (SNP) | VAF 40/322 reads (12%) | catalogued as COSV61001246; called by muse, mutect2, varscan2
- ASIC4 | c.351C>G p.L117= | Silent (SNP) | VAF 110/926 reads (12%) | called by muse, mutect2, varscan2
- ATAD2B | c.1236A>G p.L412= | Silent (SNP) | VAF 57/183 reads (31%) | catalogued as rs1303096089; called by muse, mutect2, varscan2
- BCLAF1 | c.1152C>T p.F384= | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- CABIN1 | c.5289G>A p.T1763= | Silent (SNP) | VAF 89/775 reads (11%) | catalogued as rs747411932; called by muse, mutect2, varscan2
- CCDC172 | c.48G>A p.Q16= | Silent (SNP) | VAF 111/273 reads (41%) | called by muse, varscan2
- CD300A | c.69C>A p.T23= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs202135672; called by muse, mutect2, varscan2
- CDK15 | c.1307G>A p.*436= (on ENST00000652192 / NM_001366386.2; = p.*385= on NM_139158.2) | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- CIT | c.5139C>G p.L1713= | Silent (SNP) | VAF 51/303 reads (17%) | called by muse, mutect2, varscan2
- CKB | c.636C>G p.P212= | Silent (SNP) | VAF 109/199 reads (55%) | catalogued as rs373730099; called by muse, mutect2, varscan2
- COLGALT1 | c.1191G>T p.R397= | Silent (SNP) | VAF 68/163 reads (42%) | called by muse, mutect2, varscan2
- CRTC3 | c.1515G>A p.Q505= | Silent (SNP) | VAF 50/373 reads (13%) | catalogued as rs1232102429; called by muse, mutect2, varscan2
- CUX2 | c.2517G>T p.A839= | Silent (SNP) | VAF 92/232 reads (40%) | called by muse, varscan2
- CYP46A1 | c.48C>T p.F16= | Silent (SNP) | VAF 83/363 reads (23%) | catalogued as rs569975911; called by muse, mutect2, varscan2
- DAAM1 | c.459C>A p.I153= | Silent (SNP) | VAF 34/78 reads (44%) | called by muse, varscan2
- DBNDD1 | c.216C>T p.F72= (on ENST00000002501 / NM_001042610.3; = p.F92= on NM_024043.3) | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs764814543; called by muse, mutect2, varscan2
- DDI1 | c.1164C>T p.V388= | Silent (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- DGCR2 | c.1323C>T p.I441= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as rs747442630, COSV54218761; called by muse, mutect2
- DOK6 | c.981C>A p.S327= | Silent (SNP) | VAF 60/200 reads (30%) | called by muse, mutect2, varscan2
- EHHADH | c.1059G>A p.Q353= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- EIF2B5 | c.582G>A p.K194= (on ENST00000647909; = p.K186= on NM_003907.3) | Silent (SNP) | VAF 70/1186 reads (6%) | called by muse, mutect2
- ELFN2 | c.255C>T p.N85= | Silent (SNP) | VAF 289/690 reads (42%) | called by muse, mutect2, varscan2
- EPB41L4B | c.558G>A p.R186= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- EPHB1 | c.1704T>A p.A568= | Silent (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- EZHIP | c.414G>A p.Q138= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- FASN | c.3780C>T p.L1260= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV60750746; called by muse, mutect2, varscan2
- FSIP2 | c.11238C>A p.S3746= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- FUT11 | c.969G>C p.L323= | Silent (SNP) | VAF 53/250 reads (21%) | called by muse, mutect2, varscan2
- GIMAP1 | c.159C>T p.F53= | Silent (SNP) | VAF 108/237 reads (46%) | catalogued as COSV56189348; called by muse, mutect2, varscan2
- GMCL2 | c.408C>T p.F136= | Silent (SNP) | VAF 48/181 reads (27%) | called by muse, mutect2, varscan2
- GPR55 | c.621C>A p.I207= | Silent (SNP) | VAF 163/286 reads (57%) | called by muse, mutect2, varscan2
- GRK1 | c.855G>A p.E285= | Silent (SNP) | VAF 310/467 reads (66%) | called by muse, mutect2, varscan2
- GSS | c.993C>T p.L331= | Silent (SNP) | VAF 18/367 reads (5%) | catalogued as COSV53623551, COSV53628484; called by muse, mutect2
- GUCY2C | c.195G>A p.V65= | Silent (SNP) | VAF 54/263 reads (21%) | called by muse, mutect2, varscan2
- IGKV3-7 | c.207C>T p.I69= | Silent (SNP) | VAF 306/814 reads (38%) | called by muse, mutect2, varscan2
- JHY | c.111G>A p.R37= | Silent (SNP) | VAF 35/285 reads (12%) | called by muse, mutect2, varscan2
- KCNH8 | c.1950G>T p.V650= | Silent (SNP) | VAF 52/136 reads (38%) | called by muse, varscan2
- KLHL10 | c.1620C>T p.T540= | Silent (SNP) | VAF 28/220 reads (13%) | called by muse, mutect2, varscan2
- LAMA5 | c.8733C>T p.S2911= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as rs767722075; called by muse, mutect2, varscan2
- LINGO1 | c.210C>A p.P70= | Silent (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- LINGO3 | c.795G>A p.A265= | Silent (SNP) | VAF 269/506 reads (53%) | catalogued as rs372130296; called by muse, mutect2, varscan2
- MAST1 | c.1974G>A p.Q658= | Silent (SNP) | VAF 167/341 reads (49%) | catalogued as rs1342774889, COSV52246956; called by muse, mutect2, varscan2
- MMS19 | c.69C>T p.F23= | Silent (SNP) | VAF 187/398 reads (47%) | catalogued as rs1365514775; called by muse, mutect2, varscan2
- MPIG6B | c.306C>T p.D102= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as rs775790329; called by muse, mutect2
- MTUS2 | c.2163G>A p.P721= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs201373243; called by muse, mutect2, varscan2
- MYB | c.1911G>A p.T637= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as rs768796138; called by muse, mutect2, varscan2
- MYO7A | c.2970C>T p.D990= | Silent (SNP) | VAF 66/550 reads (12%) | catalogued as rs782703928; called by muse, mutect2, varscan2
- NCAPD2 | c.1647C>T p.F549= | Silent (SNP) | VAF 46/279 reads (16%) | called by muse, mutect2, varscan2
- NEUROD1 | c.325C>A p.R109= | Silent (SNP) | VAF 219/772 reads (28%) | called by muse, mutect2, varscan2
- NLRP12 | c.1560C>T p.F520= | Silent (SNP) | VAF 264/543 reads (49%) | called by muse, mutect2, varscan2
- OR4A16 | c.135G>T p.V45= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as COSV59041957; called by muse, mutect2, varscan2
- OR6F1 | c.27C>A p.P9= | Silent (SNP) | VAF 66/124 reads (53%) | called by mutect2, varscan2
- PACSIN2 | c.66G>A p.G22= | Silent (SNP) | VAF 46/467 reads (10%) | catalogued as rs746332629; called by muse, mutect2, varscan2
- PAICS | c.702C>T p.L234= | Silent (SNP) | VAF 90/153 reads (59%) | called by muse, mutect2, varscan2
- PAK5 | c.2037G>A p.L679= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV62034813; called by muse, mutect2, varscan2
- PCDHA13 | c.1692G>T p.A564= | Silent (SNP) | VAF 258/538 reads (48%) | catalogued as COSV99165586; called by muse, mutect2, varscan2
- PCK2 | c.1617G>A p.E539= | Silent (SNP) | VAF 37/211 reads (18%) | catalogued as rs1175262229; called by muse, mutect2, varscan2
- PKN1 | c.1314G>A p.Q438= | Silent (SNP) | VAF 84/259 reads (32%) | catalogued as rs1034528681; called by muse, mutect2, varscan2
- PLEKHA6 | c.3075G>T p.P1025= | Silent (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- PMFBP1 | c.990G>A p.K330= | Silent (SNP) | VAF 48/362 reads (13%) | catalogued as rs1379863745; called by muse, mutect2, varscan2
- PPP6R3 | c.120G>A p.Q40= | Silent (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- PRKCB | c.904C>A p.R302= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as rs536939564; called by muse, mutect2, varscan2
- PUS7L | c.1383T>C p.F461= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV100786564; called by muse, mutect2
- REX1BD | c.477G>A p.E159= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2
- RNASEL | c.924G>A p.A308= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as rs375420925; called by muse, mutect2, varscan2
- ROBO3 | c.1023C>T p.L341= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as COSV101185180; called by muse, mutect2
- ROCK2 | c.1719A>G p.T573= | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- RPL13 | c.174C>A p.I58= | Silent (SNP) | VAF 77/391 reads (20%) | catalogued as rs1269016927; called by muse, mutect2, varscan2
- RPL13 | c.471C>T p.V157= | Silent (SNP) | VAF 42/225 reads (19%) | called by muse, mutect2, varscan2
- RSF1 | c.87C>T p.F29= | Silent (SNP) | VAF 342/753 reads (45%) | catalogued as rs908140819; called by muse, mutect2, varscan2
- RUBCN | c.2469C>T p.F823= | Silent (SNP) | VAF 51/803 reads (6%) | called by muse, mutect2
- RYR2 | c.6582C>T p.A2194= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as COSV63712693; called by muse, mutect2, varscan2
- SEMA3E | c.2169G>A p.Q723= | Silent (SNP) | VAF 123/358 reads (34%) | called by muse, mutect2, varscan2
- SETD1B | c.5334C>A p.T1778= | Silent (SNP) | VAF 21/100 reads (21%) | called by mutect2, varscan2
- SGK2 | c.369G>A p.V123= | Silent (SNP) | VAF 111/283 reads (39%) | called by muse, mutect2, varscan2
- SLC16A8 | c.900C>T p.I300= | Silent (SNP) | VAF 139/609 reads (23%) | called by muse, mutect2, varscan2
- SOGA3 | c.2547C>T p.N849= | Silent (SNP) | VAF 91/576 reads (16%) | catalogued as rs376377098; called by muse, mutect2, varscan2
- SORL1 | c.3267C>T p.N1089= | Silent (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- SPTBN1 | c.2886C>T p.L962= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs1417649074; called by muse, mutect2
- STAB2 | c.6604C>T p.L2202= | Silent (SNP) | VAF 69/164 reads (42%) | called by muse, mutect2, varscan2
- TAOK3 | c.798A>G p.P266= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- TCEA2 | c.471G>A p.V157= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as rs759074461; called by muse, mutect2, varscan2
- TLR10 | c.84G>A p.R28= | Silent (SNP) | VAF 84/163 reads (52%) | called by muse, mutect2, varscan2
- TMEM45B | c.204G>C p.P68= | Silent (SNP) | VAF 113/342 reads (33%) | catalogued as COSV99859347; called by muse, mutect2, varscan2
- TPP2 | c.2337G>A p.L779= | Silent (SNP) | VAF 45/307 reads (15%) | called by muse, mutect2, varscan2
- TRANK1 | c.1974A>C p.A658= | Silent (SNP) | VAF 95/195 reads (49%) | called by muse, mutect2, varscan2
- TRDN | c.2094T>C p.N698= | Silent (SNP) | VAF 64/222 reads (29%) | called by muse, mutect2, varscan2
- TRIM15 | c.21G>A p.L7= | Silent (SNP) | VAF 116/237 reads (49%) | called by muse, mutect2
- TRPS1 | c.2556C>T p.F852= (on ENST00000220888 / NM_001330599.2; = p.F865= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as COSV55255315; called by muse, mutect2, varscan2
- TSC22D1 | c.1815A>G p.L605= | Silent (SNP) | VAF 162/253 reads (64%) | catalogued as rs368497303; called by muse, mutect2, varscan2
- VPS13C | c.7659T>A p.I2553= (on ENST00000644861 / NM_020821.3; = p.I2510= on NM_017684.5) | Silent (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- WFDC1 | c.63C>G p.L21= | Silent (SNP) | VAF 67/404 reads (17%) | catalogued as COSV54743912; called by muse, mutect2, varscan2
- ZNF337 | c.87G>A p.L29= | Silent (SNP) | VAF 77/240 reads (32%) | called by muse, mutect2, varscan2
- ZNF441 | c.450C>T p.F150= | Silent (SNP) | VAF 44/203 reads (22%) | called by muse, mutect2, varscan2
- ABL2 | c.1652-322T>C | Intron (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-7091G>C | Intron (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851440 C>A | 3'Flank (SNP) | VAF 148/224 reads (66%) | called by muse, mutect2, varscan2
- ANXA2 | c.-117+23G>T | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- ANXA2P2 | n.372C>A | RNA (SNP) | VAF 86/459 reads (19%) | catalogued as rs772047075; called by muse, mutect2, varscan2
- AP5Z1 | c.1806-174C>G | Intron (SNP) | VAF 57/367 reads (16%) | called by muse, mutect2, varscan2
- B3GNT7 | c.-39C>G | 5'UTR (SNP) | VAF 40/56 reads (71%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3650G>T | Intron (SNP) | VAF 54/140 reads (39%) | called by muse, mutect2, varscan2
- C12orf42 | c.259+790A>T | Intron (SNP) | VAF 59/172 reads (34%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2210G>A | Intron (SNP) | VAF 26/99 reads (26%) | catalogued as COSV53793671; called by muse, mutect2, varscan2
- CCDC150 | c.1866+690G>T | Intron (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- CCDC85C | c.*8085del | 3'UTR (DEL) | VAF 26/173 reads (15%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.192-46C>T | Intron (SNP) | VAF 70/137 reads (51%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+202C>T | Intron (SNP) | VAF 91/498 reads (18%) | catalogued as rs749766387; called by muse, mutect2, varscan2
- CNOT4 | c.*6G>C | 3'UTR (SNP) | VAF 22/263 reads (8%) | called by muse, mutect2
- COX20 | c.-38C>A | 5'UTR (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- CROCC2 | c.4557+442G>A | Intron (SNP) | VAF 16/279 reads (6%) | catalogued as rs1023676400; called by muse, mutect2
- CTIF | c.*372C>T | 3'UTR (SNP) | VAF 38/228 reads (17%) | catalogued as rs753618655; called by muse, mutect2, varscan2
- DCAF17 | c.*2914G>A | 3'UTR (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2
- DIO3 | chr14:101557692 G>A | 5'Flank (SNP) | VAF 91/175 reads (52%) | called by muse, mutect2, varscan2
- DNAJC4 | c.-454G>A | 5'UTR (SNP) | VAF 18/440 reads (4%) | catalogued as COSV99655752; called by muse, mutect2
- ESR1 | c.452+820C>G | Intron (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- F5 | c.-35G>A | 5'UTR (SNP) | VAF 81/426 reads (19%) | called by muse, mutect2, varscan2
- FHL1 | c.-26-9275C>T | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- G6PC3 | c.218+635C>T | Intron (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1902-11del | Intron (DEL) | VAF 136/491 reads (28%) | called by mutect2, pindel*, varscan2*
- H2AZ2 | chr7:44822046 C>G | 3'Flank (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.-64G>A | 5'UTR (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- HSP90B3P | n.927G>A | RNA (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- KCNH2 | c.*40C>G | 3'UTR (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1474+74C>A | Intron (SNP) | VAF 78/269 reads (29%) | called by muse, mutect2, varscan2
- LEKR1 | c.*943G>C | 3'UTR (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- MIER1 | c.*1543C>T | 3'UTR (SNP) | VAF 29/202 reads (14%) | catalogued as rs1197555796; called by muse, mutect2, varscan2
- MIR513A2 | n.41A>T | RNA (SNP) | VAF 53/76 reads (70%) | called by muse, mutect2, varscan2
- MRPL49 | c.*1174G>A | 3'UTR (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.693A>C | RNA (SNP) | VAF 19/233 reads (8%) | called by muse, mutect2
- NIPA1 | c.-3G>C | 5'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- NRBF2 | c.-111C>T | 5'UTR (SNP) | VAF 14/211 reads (7%) | catalogued as rs1448069806; called by muse, mutect2
- NRG1 | c.502+30867C>T | Intron (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- NSL1 | c.499+16105A>G | Intron (SNP) | VAF 18/90 reads (20%) | catalogued as rs890044155; called by muse, mutect2, varscan2
- NUP62CL | c.*26G>T | 3'UTR (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- NUP62CL | c.*25G>A | 3'UTR (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- PLCD1 | c.35-4399C>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs924647069; called by muse, varscan2
- POMGNT1 | c.*343G>T | 3'UTR (SNP) | VAF 90/181 reads (50%) | catalogued as rs368285518; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-1955G>A | Intron (SNP) | VAF 34/205 reads (17%) | catalogued as COSV56897293; called by muse, mutect2, varscan2
- PTPRVP | n.4144-30_4144-29insCCTTGCTCCTCGCTCCTCGCTCCTCGCT | Intron (INS) | VAF 107/704 reads (15%) | called by mutect2, varscan2*
- PTTG1IP | c.*81A>G | 3'UTR (SNP) | VAF 193/479 reads (40%) | catalogued as rs1165364352; called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44462082 C>A | 3'Flank (SNP) | VAF 105/273 reads (38%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+8361C>A | Intron (SNP) | VAF 316/475 reads (67%) | catalogued as rs200203262, COSV54374316, COSV54376037; called by muse, mutect2, varscan2
- SLC25A29 | c.79-2280G>T | Intron (SNP) | VAF 107/204 reads (52%) | called by muse, mutect2, varscan2
- SLC27A1 | c.1206+57C>G | Intron (SNP) | VAF 97/400 reads (24%) | called by muse, mutect2, varscan2
- SPG7 | c.758+21G>T | Intron (SNP) | VAF 55/394 reads (14%) | called by muse, mutect2, varscan2
- SPTA1 | c.6788+39G>C | Intron (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- SSX9P | n.564G>A | RNA (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- STK26 | c.-18G>T | 5'UTR (SNP) | VAF 98/327 reads (30%) | called by muse, mutect2, varscan2
- TAF15 | c.-38C>A | 5'UTR (SNP) | VAF 107/694 reads (15%) | called by muse, mutect2, varscan2
- TOX2 | c.*226C>A | 3'UTR (SNP) | VAF 44/233 reads (19%) | called by muse, mutect2, varscan2
- TPRX2P | n.504G>T | RNA (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- TVP23C | chr17:15565536 G>A | 5'Flank (SNP) | VAF 165/567 reads (29%) | called by muse, mutect2, varscan2
- USP15 | c.683+2400G>T | Intron (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- VMA21 | chrX:151396971 C>T | 5'Flank (SNP) | VAF 131/200 reads (66%) | called by muse, mutect2, varscan2
- ZNF559 | chr19:9324161 G>T | 5'Flank (SNP) | VAF 111/225 reads (49%) | called by muse, mutect2, varscan2
- ZNF658B | n.2438G>T | RNA (SNP) | VAF 63/120 reads (53%) | called by mutect2, varscan2
